Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A3A5, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A3A5-01A (Primary Tumor).

Patient Key:

Surgical date:

TISSUE DESCRIPTION:

Segments II and III left lobe liver (620 grams, 18 x 11 x 9.5 cm) and specimen from right lobe liver (biopsy, 1.3 x 0.8 x 0.3 cm). A1, B1, B2, B3, B4, B5, B6

DIAGNOSIS:

Left liver, segments II and III: Grade 2 hepatocellular carcinoma is identified forming a yellow-white, multilobulated mass, 11 x 10 x 9.5 cm. Adjacent to the large mass, there is a separate tumor mass, 1.3 x 1.2 x 1 cm. The hepatic parenchyma is noncirrhotic and the margin of resection is free of involvement; closest surgical margin 0.5 cm. () Right liver biopsy: Benign liver tissue.

1CD-0-3

carcinoma, hepatocellular, NOS 8170/3

Site: Liver C22.0
9/22/11

Source: NCI Genomic Data Commons file 10e7ad90-dbb7-4f40-9156-06c827e40cf6 (TCGA-DD-A3A5.646F2FED-EA95-4758-B454-4B0E638553B4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).